Somatic mutation profile of tumor specimen C3N-03239-01 (aliquot CPT0194050010) from CPTAC case C3N-03239, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.0 years (25,197 days).
Specimen C3N-03239-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27f34688-5fb8-492d-86b8-1fc98bd501cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03239-71 (Blood Derived Normal), aliquot CPT0194170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/648242ab-043f-466d-ae4a-ace81ee91062

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 13, Silent 8, Frame Shift Ins 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH7 | c.2299C>T p.L767F | Missense Mutation (SNP) | VAF 170/459 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.827); catalogued as COSV100415697; called by muse, mutect2, varscan2
- DNM1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 228/605 reads (38%) | catalogued as COSV57851054, COSV57851420, COSV57852347; called by muse, mutect2, varscan2
- GLYATL3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 268/639 reads (42%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs543012165; called by muse, mutect2, varscan2
- KALRN | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 232/344 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs765655082; called by muse, mutect2, varscan2
- ABCA2 | c.366G>C p.T122= (on ENST00000614293; = p.T92= on NM_001606.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 151/395 reads (38%) | called by muse, mutect2, varscan2
- AUP1 | c.546A>T p.Q182H | Missense Mutation (SNP) | VAF 118/327 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- COL20A1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 237/610 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL3A1 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 204/480 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB4 | c.636dup p.R213Sfs*10 | Frame Shift Ins (INS) | VAF 240/745 reads (32%) | called by mutect2, pindel, varscan2
- FAM120C | c.1769G>T p.R590M | Missense Mutation (SNP) | VAF 293/452 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GSK3B | c.1005T>A p.C335* (on ENST00000264235 / NM_001146156.2; = p.C348* on NM_002093.4) | Nonsense Mutation (SNP) | VAF 169/273 reads (62%) | called by muse, mutect2, varscan2
- GTF3C6 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 182/460 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, varscan2
- LAD1 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 161/424 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGA | c.1408dup p.Y470Lfs*13 | Frame Shift Ins (INS) | VAF 158/238 reads (66%) | called by mutect2, varscan2
- MGA | c.1409delinsTT p.Y470Ffs*13 | Frame Shift Ins (INS) | VAF 169/407 reads (42%) | called by mutect2*, pindel, varscan2*
- MTMR10 | c.1571_1574del p.I524Nfs*8 | Frame Shift Del (DEL) | VAF 162/464 reads (35%) | called by mutect2, pindel, varscan2
- TBC1D17 | c.936C>A p.S312R | Missense Mutation (SNP) | VAF 127/265 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- TMEM139 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 241/671 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TUBD1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATP10A | c.223C>T p.L75= | Silent (SNP) | VAF 202/550 reads (37%) | catalogued as rs532896913; called by muse, mutect2, varscan2
- BBS12 | c.1416C>T p.T472= | Silent (SNP) | VAF 201/549 reads (37%) | catalogued as rs1185306509; called by muse, mutect2, varscan2
- FASN | c.2022G>A p.E674= | Silent (SNP) | VAF 196/563 reads (35%) | catalogued as rs1336316361; ClinVar: likely benign; called by muse, mutect2, varscan2
- FUZ | c.1236T>C p.H412= | Silent (SNP) | VAF 100/228 reads (44%) | called by muse, varscan2
- H2AP | c.123C>T p.D41= | Silent (SNP) | VAF 298/437 reads (68%) | catalogued as rs1327386210; called by muse, mutect2, varscan2
- ITGAX | c.2220C>A p.G740= | Silent (SNP) | VAF 200/498 reads (40%) | called by muse, mutect2, varscan2
- PLK5 | c.438G>A p.L146= | Silent (SNP) | VAF 145/297 reads (49%) | called by muse, mutect2, varscan2
- RNF186 | c.459G>A p.R153= | Silent (SNP) | VAF 215/333 reads (65%) | catalogued as rs757256378; called by muse, mutect2, varscan2
